Gene-level copy-number profile of tumor specimen TCGA-L5-A8NM-01A from TCGA case TCGA-L5-A8NM, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 84.7 years (30,936 days).
Specimen TCGA-L5-A8NM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.ee74e402-5d8c-42bb-a7a7-cf78e3f2f720.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-L5-A8NM-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26f5ea40-1f97-4cc8-9dac-49c5d7150864

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,471; copy number 2: 54,830; copy number 3: 2,519.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-L5-A8NM-01A-11D-A37B-01): tumor purity 0.27, ploidy 2.12, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 50. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
